FM case AD5962 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Retroperitoneum and peritoneum.
https://portal.gdc.cancer.gov/cases/7149a99c-b5bf-4885-bd73-d690fc72a84b

Female, 66.3 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the peritoneum; metastasis biopsied or resected from the liver. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
